TCGA case TCGA-DX-A7ER — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Synovial-like Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a7c45269-b693-45c4-81fd-6dd3379877e8

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Dead; Days to death: 1,466 days (4.0 years).

Diagnoses (1)
1. Synovial sarcoma, spindle cell: ICD-O-3 morphology code: 9041/3; ICD-10 code: C49.3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of thorax; Classification of tumor: primary; Age at diagnosis: 69.4 years (25,363 days); Year of diagnosis: 2008; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2.8; Tumor length measurement: 20; Tumor width measurement: 18.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 40; Necrosis present: Yes; Tumor depth descriptor: Deep.

Follow-up (1 entry)
- Days to follow up: 1,466 days (4.0 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A7ER-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 440 mg.
  Slide TCGA-DX-A7ER-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A7ER-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A7ER-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Synovial Sarcoma - Monophasic; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Chest - Lung/pleura.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,466 days; disease-specific survival: no event (censored), 1,466 days; disease-free interval: no event (censored), 1,466 days; progression-free interval: no event (censored), 1,466 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A7ER-01A-11D-A40C-01): tumor purity 0.98, ploidy 2, whole-genome doublings 0.
